Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A23Z, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A23Z-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

ICD-0-3

dedifferentiated liposarcoma 8858/.

Site: retroperitoneum C48.0

4/21/11

.....
Clinical Diagnosis & History:

y/o male with a left sided retroperitoneal sarcoma.

Specimens Submitted:

1: SP: Radical resection of retroperitoneal sarcoma spleen and left colon

2: SP: Distal left colon

DIAGNOSIS:

- 1) SOFT TISSUE, RETROPERITONEAL SARCOMA WITH COLON, KIDNEY, ADRENAL GLAND AND SPLEEN; EN BLOC RESECTION:
- DEDIFFERENTIATED LIPOSARCOMA.
- WELL DIFFERENTIATED COMPONENT ENCASES KIDNEY, FOCALLY INVADES COLON AND SKELETAL MUSCLE, AND MEASURES 17 CM GREATEST DIMENSION; NONLIPOGENIC ELEMENT GROWS AS GROSSLY SEPARATE NODULES (WITH HISTOLOGIC APPEARANCE OF PLEOMORPHIC AND SPINDLE CELL HIGH GRADE SARCOMA) MEASURING UP TO 6.5 GREATEST DIMENSION WHICH FOCALLY INVADE RENAL CORTEX.
- WELL DIFFERENTIATED LIPOSARCOMA FOCALLY EXTENDS TO INKED SOFT TISSUE MARGIN AND INVOLVES ONE UNDESIGNATED COLONIC MARGIN.
- NO TUMOR NECROSIS IS SEEN.
- SPLEEN AND ADRENAL GLAND ARE HISTOLOGICALLY UNREMARKABLE.
- COLONIC TUBULAR ADENOMA.
- KIDNEY WITH SIMPLE RENAL CYST, FOCAL SCLEROTIC GLOMERULI, AND INTIMAL THICKENING IN INTERLOBULAR ARTERIES.
- ONE BENIGN LYMPH NODE.
- 2) COLON, DISTAL LEFT; RESECTION:
- HISTOLOGICALLY UNREMARKABLE COLON AND ADIPOSE TISSUE.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

** Continued on next page **

[page 2 of 3]
1). The specimen is received fresh, labeled "Radical resection of retroperitoneal sarcoma spleen and left colon" and consists of an en bloc segment of colon, kidney and adrenal gland. There is a separate spleen. The specimen measures 35 x 25 x 8 cm in aggregate. Two nodules are identified on the peritoneal surface, measuring 0.4 x 0.4 x 0.2 cm and 0.3 x 0.3 x 0.2 cm; sectioning reveals white cut surfaces. The colon measures 67.5 cm in length and 3.5 cm in average diameter, no orientation is provided. The outer surface is pink-tan smooth, except one area with firm mesocolic fat which appears fixed to the colon. This area is about 18.5 cm from one margin. There is a piece of skeletal muscle attached to the colon, measuring 6.5 x 3 x 1 cm. Colonic mucosa shows two pink-tan polyps measuring 0.5 x 0.3 x 0.3 cm and 0.2 x 0.2 x 0.1 cm. The polyps are about 29.5 cm from one margin. The two polyps are about 2 cm apart. Serial sectioning of the colon reveals the polyps are confined to mucosa. Beneath the firm area is a white-tan, well demarcated nodule, measuring 1.8 x 1.5 cm. A few lymph nodes are collected. The kidney measures 8 x 5 x 4 cm and is encased in coarsely lobulated, abnormally firm fat. An unremarkable adrenal gland is identified measuring 3 x 0.8 x 0.8 cm. No lymph node is identified in hilum area. The ureter segment measures 0.3 cm. Sectioning of the kidney reveals well demarcated mass in the lower pole of the kidney and perinephric fat measuring 6.5 x 5 x 4.5 cm. The mass compress the renal pelvis. It has a white firm cut surface. There is a separate white nodule in the perinephric fat, measuring 1.5 x 1.2 x 1 cm. No other renal lesion is identified. TPS and gross photos are taken. The spleen measures 12 x 8 x 3.5 cm. The outer surface and cut surface are unremarkable. Representative sections are submitted.

Summary of sections.

KM kidney ureter and vascular margin.
M tumor peritoneal margin.
CM1 one colon margin, shaved
CM2 opposite colon margin, shaved
TK tumor with kidney
T tumor
MN mesentery nodule with colon
P1 peritoneal nodule 1
P2 peritoneal nodule 2
SKM skeletal muscle
NSP normal spleen
NK normal kidney
NAD normal adrenal gland
NF normal firm fat.
LN possible lymph nodes
NN separated nodule in the perinephric fat.

2.) The specimen is received fresh, labeled "distal left colon" and consists of a 9 cm long, 5.5 cm circumference portion of colon. The serosal surface

** Continued on next page **

[page 3 of 3]
----- Page 3 of 3
is smooth. No lesions are identified grossly. A portion of normal fat is
submitted for ' Representative sections are submitted.

Summary of sections:

M1 - margin 1
M2 - margin 2
R - representative
LN - lymph nodes

Summary of Sections:

Part 1: SP: Radical resection of retroperitoneal sarcoma spleen and left
colon

Block	Sect. Site	PCs
1	CM1	1
1	CM2	1
1	KM	1
2	LN	2
2	M	2
4	MN	4
1	NAD	1
1	NF	1
1	NK	1
2	NN	2
1	NSP	1
2	P1	2
1	P2	1
2	SKM	2
4	T	4
4	TK	4

Part 2: SP: Distal left colon

Block	Sect. Site	PCs
2	LN	2
1	M1	1
1	M2	1
2	R	2

** End of Report **

Reviewer Initials	WJ	Reviewed

4/2/14

Source: NCI Genomic Data Commons file ffb4776a-c483-4916-a73f-b43c0cd13d60 (TCGA-DX-A23Z.70241F3B-CB2A-4DD9-ABF9-1F300C5AD7DF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).